APOLLO case AP-NEKQ — APOLLO2: Proteogenomic characterization of ovarian serous cystadenocarcinoma (APOLLO-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/24611ad1-cd7a-44c1-a71c-2a53eb3077a6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead.

Diagnoses (1)
1. High-grade serous carcinoma: Tissue or organ of origin: Ovary; Site of resection or biopsy: Uterus, NOS; Classification of tumor: metastasis; Age at diagnosis: 49.0 years (17,889 days); Residual disease: R1.

Biospecimens (2 samples)
- Sample AP-NEKQ_normal: Tissue type: Normal; Specimen type: Peripheral Blood NOS; Biospecimen anatomic site: Uterus; Preservation method: Frozen.
- Sample AP-NEKQ_tumor: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: OCT; Diagnosis pathologically confirmed: Yes.
